CCDI case PBCECL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/5c174a43-b2fa-49b0-bad7-08f8652f1c74

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 1.0 years (382 days).

Biospecimens (4 samples)
- Sample 0DPSN6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPSNF, 0DPSNH, 0DPUTN (3 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
